Somatic mutation profile of tumor specimen TCGA-FW-A5DY-06A (aliquot TCGA-FW-A5DY-06A-11D-A30X-08) from TCGA case TCGA-FW-A5DY, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 48.7 years (17,790 days).
Specimen TCGA-FW-A5DY-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d07b8659-ec7b-4fc2-89ab-ceb298e80c62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FW-A5DY-11A (Solid Tissue Normal), aliquot TCGA-FW-A5DY-11A-12D-A30X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f51ad21-0c81-4a6b-83b7-a2577cc51a86

The open-access MAF lists 153 somatic variants for this specimen: 104 protein-altering or splice-affecting, 47 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 95, Silent 47, Nonsense Mutation 5, Splice Site 2, Splice Region 2, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG4 | c.7354C>T p.P2452S | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV54956055; called by muse, mutect2
- ARHGAP30 | c.544G>A p.D182N | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63517328; called by muse, mutect2, varscan2
- ASTN1 | c.3274C>T p.P1092S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.94); PolyPhen probably damaging (0.991); catalogued as COSV62490321; called by mutect2, varscan2
- ATP7A | c.4271G>A p.S1424N | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV58448401; called by muse, mutect2
- B3GALT1 | c.784C>T p.H262Y | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as COSV59909063; called by muse, mutect2
- CACNA1S | c.4906G>A p.E1636K | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.524); catalogued as COSV62940927; called by muse, mutect2, varscan2
- CAPZA3 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.8); PolyPhen benign (0.017); catalogued as COSV56854582; called by muse, mutect2
- CARD6 | c.2400G>A p.M800I | Missense Mutation (SNP) | VAF 30/444 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV54564513; called by muse, mutect2
- CCDC185 | c.1204G>A p.V402M | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); catalogued as COSV100838832; called by muse, mutect2
- CCDC27 | c.712-1G>A p.X238_splice | Splice Site (SNP) | VAF 7/49 reads (14%) | catalogued as COSV53901260; called by muse, mutect2, varscan2
- CDK17 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.021); catalogued as COSV54130753; called by muse, mutect2
- COL21A1 | c.2309G>A p.G770E | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55168273, COSV99777916; called by muse, mutect2
- COL5A1 | c.4594C>T p.P1532S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV65669432; called by muse, mutect2
- COL9A2 | c.1000G>A p.G334S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV65607713; called by muse, mutect2
- CT55 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV52278148, COSV99358770; called by muse, mutect2, varscan2
- DACT1 | c.1571C>T p.P524L | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.466); catalogued as COSV60021645; called by muse, mutect2
- DSG4 | c.1687G>A p.E563K | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as COSV57389534; called by mutect2, varscan2
- EAPP | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as rs781306099, COSV51651534; called by muse, mutect2, varscan2
- EGF | c.2222-1G>A p.X741_splice | Splice Site (SNP) | VAF 8/82 reads (10%) | catalogued as COSV54480496; called by muse, mutect2
- ERN2 | c.1022G>A p.S341N | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV56834946, COSV99892183; called by muse, mutect2
- FLG | c.4391G>A p.G1464E | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT tolerated (1); PolyPhen possibly damaging (0.746); catalogued as COSV64243483; called by muse, varscan2
- FMO1 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.114); catalogued as COSV61446358; called by muse, mutect2, varscan2
- GABRA6 | c.1105C>T p.H369Y | Missense Mutation (SNP) | VAF 4/97 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV50878657; called by muse, mutect2
- GALNT17 | c.1673G>A p.G558E | Missense Mutation (SNP) | VAF 10/123 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.33); catalogued as COSV61164384; called by muse, mutect2
- GLIS1 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426949401, COSV56550901; called by muse, mutect2
- GNA14 | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs200863618, COSV59021467; called by muse, mutect2
- GOLGB1 | c.8353C>T p.L2785F | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.203); catalogued as COSV61461356, COSV61467256; called by muse, mutect2
- GPR156 | c.1306C>T p.P436S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs760322398, COSV59940741; called by mutect2, varscan2
- GRIN2A | c.3373G>A p.E1125K | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.482); catalogued as rs1200593226, COSV58026502, COSV58058380; called by muse, mutect2
- GRM6 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 12/191 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV51434523, COSV51444361; called by muse, mutect2
- HDAC8 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65266195, COSV65267020; called by muse, mutect2
- HEG1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.005); catalogued as COSV60763267; called by muse, mutect2
- HYDIN | c.1841C>T p.S614L | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as rs866516677, COSV55478311; called by muse, mutect2
- INTU | c.2126C>T p.P709L | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as COSV58872670; called by muse, mutect2
- ITIH2 | c.1818A>C p.R606S | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.662); catalogued as COSV64433874; called by muse, mutect2
- KCNB1 | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65569037; called by muse, mutect2, varscan2
- KCNH7 | c.2734G>A p.D912N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV59801106; called by muse, mutect2
- KCNJ4 | c.1313C>T p.S438F | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV57857606; called by muse, mutect2
- KIF12 | c.1198C>T p.Q400* (on ENST00000640217; = p.Q262* on NM_138424.1) | Nonsense Mutation (SNP) | VAF 8/118 reads (7%) | catalogued as COSV65117572; called by muse, mutect2
- KLHL15 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60140786; called by muse, mutect2
- KRT38 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.826); catalogued as COSV55846485; called by muse, mutect2
- LCE1F | c.158G>A p.G53D | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.26); catalogued as COSV57669385, COSV57669450; called by muse, mutect2, varscan2
- LGR5 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as COSV57006378, COSV99877989; called by muse, mutect2
- LMTK3 | c.2669C>T p.A890V | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as rs1396536375; called by muse, mutect2
- LRRC15 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.277); catalogued as rs267599744, COSV61650505; called by muse, mutect2
- MAP1A | c.6879G>A p.M2293I | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV100289137; called by muse, mutect2
- MAP1A | c.6880G>A p.E2294K | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.475); catalogued as COSV100289140; called by muse, mutect2
- MAP2 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.156); catalogued as COSV99558600, COSV99561504; called by muse, mutect2, varscan2
- MAP7D2 | c.759G>A p.V253= | Splice Region (SNP) | VAF 8/195 reads (4%) | catalogued as COSV65528218; called by muse, mutect2
- MARVELD2 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as COSV57781192; called by muse, mutect2
- MCOLN2 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs764082069, COSV52296832; called by muse, mutect2
- MGAT5 | c.536A>T p.D179V | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV56097802; called by muse, mutect2
- MUC16 | c.20213G>A p.R6738Q | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67474551; called by muse, mutect2, varscan2
- MUC16 | c.14601G>A p.M4867I | Missense Mutation (SNP) | VAF 16/146 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.012); catalogued as rs550349238, COSV67442601; called by muse, mutect2, varscan2
- MUC16 | c.11266G>A p.G3756R | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as COSV67475659; called by muse, mutect2
- NEU2 | c.1012C>T p.Q338* | Nonsense Mutation (SNP) | VAF 8/156 reads (5%) | catalogued as COSV52093175; called by muse, mutect2
- NRK | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.154); catalogued as COSV54599540; called by muse, mutect2
- NUTM1 | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61547533; called by muse, mutect2
- OR10A6 | c.275T>G p.I92S | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59165359; called by muse, mutect2, varscan2
- OR10Z1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs762941391, COSV63524587, COSV63525364; called by muse, mutect2
- OR4C6 | c.280G>A p.G94S | Missense Mutation (SNP) | VAF 4/78 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.282); catalogued as COSV58604759; called by muse, mutect2
- OR4S2 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs267602971, COSV56746047; called by muse, mutect2, varscan2
- PAPPA2 | c.4327G>A p.E1443K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100868379, COSV62798918; called by muse, mutect2, varscan2
- PCSK1 | c.893G>A p.G298E | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60736088; called by muse, mutect2, varscan2
- PDHA2 | c.961A>G p.R321G | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV54779933; called by muse, mutect2, varscan2
- PHLDB2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV67312778; called by muse, mutect2
- PIGQ | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.811); catalogued as rs752008411, COSV50315569; called by muse, mutect2, varscan2
- PIP5K1B | c.356A>G p.N119S | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as COSV55250870; called by muse, mutect2
- PLCH1 | c.1997A>G p.N666S (on ENST00000340059 / NM_001130960.2; = p.N678S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58201893; called by muse, mutect2, varscan2
- PLXNA3 | c.4437C>T p.T1479= | Splice Region (SNP) | VAF 7/72 reads (10%) | catalogued as COSV63754532; called by muse, mutect2, varscan2
- PRAMEF2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs1425309394, COSV53576630; called by muse, mutect2, varscan2
- PRDM5 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV53362481; called by muse, mutect2
- PREX2 | c.3963G>C p.Q1321H | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV55779479; called by muse, mutect2
- PRSS45P | c.513G>A p.M171I | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.525); catalogued as COSV70577333; called by muse, mutect2
- PSD | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.703); catalogued as COSV50048023; called by muse, mutect2, varscan2
- REXO4 | c.785C>T p.A262V | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV64241861; called by muse, mutect2
- RFC2 | c.98A>T p.H33L | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.035); catalogued as COSV99278071; called by muse, mutect2
- RP1 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55118375; called by muse, mutect2
- SCN11A | c.2456G>A p.R819K | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV56567185, COSV56572552; called by muse, mutect2, varscan2
- SELP | c.1828G>A p.G610R | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55253848; called by muse, mutect2, varscan2
- SLC10A2 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55359965; called by muse, mutect2
- SLC4A10 | c.1228C>T p.R410C (on ENST00000446997 / NM_001354461.2; = p.R380C on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs558073659, COSV55769372; called by muse, mutect2, varscan2
- SLC6A19 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.088); catalogued as rs868381615, COSV58672214; called by muse, mutect2
- SLC7A13 | c.1040G>A p.G347E | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV52535226; called by muse, mutect2
- SMTNL2 | c.1259A>T p.E420V (on ENST00000389313 / NM_001114974.2; = p.E276V on NM_198501.3) | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58808548; called by muse, mutect2
- SPRY3 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.788); catalogued as COSV57142039; called by muse, mutect2
- STAB2 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66341395, COSV66342469; called by muse, mutect2
- TACC2 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV57760213; called by muse, mutect2, varscan2
- TG | c.4864G>A p.E1622K | Missense Mutation (SNP) | VAF 12/170 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV55081711; called by muse, mutect2
- TMF1 | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 16/212 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as rs765949482, COSV68374733; called by muse, mutect2
- TRIML1 | c.1337C>T p.S446F | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs1316000776, COSV60194018, COSV60196036; called by muse, mutect2, varscan2
- TRIP12 | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV52266700; called by muse, mutect2
- TTN | c.100480C>T p.P33494S (on ENST00000591111; = p.P26070S on NM_003319.4) | Missense Mutation (SNP) | VAF 8/164 reads (5%) | PolyPhen probably damaging (0.998); catalogued as COSV60150594; called by muse, mutect2
- TTN | c.85893G>A p.W28631* (on ENST00000591111; = p.W21207* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 10/106 reads (9%) | catalogued as COSV60048617; called by muse, mutect2
- TTN | c.25057C>T p.P8353S (on ENST00000591111; = p.P7426S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/186 reads (9%) | PolyPhen benign (0.129); catalogued as COSV60150675; called by muse, mutect2
- UGT1A5 | c.251G>A p.W84* | Nonsense Mutation (SNP) | VAF 8/82 reads (10%) | catalogued as COSV59391857; called by mutect2, varscan2
- UGT2B17 | c.273G>A p.M91I | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs1351493392, COSV58500798; called by muse, mutect2
- UNC119B | c.664C>T p.P222S | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267603342, COSV60866390; called by muse, mutect2
- USP28 | c.1027C>T p.P343S | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV50155846; called by muse, mutect2
- VGLL1 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 14/188 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV65702853, COSV65703420; called by muse, mutect2
- WNT16 | c.727G>A p.E243K (on ENST00000222462 / NM_057168.2; = p.E233K on NM_016087.2) | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.068); catalogued as COSV55976622; called by muse, mutect2
- ZNF285 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as rs748561574, COSV58409570; called by muse, mutect2
- ZSCAN20 | c.1648G>A p.A550T | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV63681403, COSV63683292; called by muse, mutect2
- OR6Q1 | c.594G>A p.W198* | Nonsense Mutation (SNP) | VAF 12/113 reads (11%) | called by muse, mutect2, varscan2
- ACAP1 | c.495G>A p.G165= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV50137213; called by muse, mutect2, varscan2
- AKR1C4 | c.489C>T p.I163= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs781906133, COSV54123890; called by muse, mutect2
- ATP7A | c.2541C>T p.I847= | Silent (SNP) | VAF 11/166 reads (7%) | catalogued as rs1569549986, COSV58448386; called by muse, mutect2
- BANK1 | c.1947C>T p.F649= | Silent (SNP) | VAF 14/144 reads (10%) | catalogued as COSV59845165; called by muse, mutect2
- BRAT1 | c.1062C>T p.L354= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV61395948; called by muse, mutect2
- C1QTNF7 | c.555C>T p.F185= | Silent (SNP) | VAF 18/282 reads (6%) | catalogued as COSV54853650; called by muse, mutect2
- CADM4 | c.438C>T p.L146= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as rs766849536, COSV55929236; called by muse, mutect2, varscan2
- CCDC185 | c.1203G>A p.L401= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100838831; called by muse, mutect2
- CD93 | c.1620C>T p.S540= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as COSV55666294; called by muse, mutect2
- COL15A1 | c.1272G>A p.G424= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV66642975; called by muse, mutect2
- DRC7 | c.837G>A p.R279= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV61055918; called by muse, mutect2
- FLNC | c.4932C>T p.S1644= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV57956029; called by muse, mutect2
- GIGYF1 | c.84C>T p.S28= | Silent (SNP) | VAF 16/87 reads (18%) | catalogued as rs766066536, COSV51943531; called by muse, mutect2, varscan2
- GLI1 | c.657G>A p.E219= | Silent (SNP) | VAF 6/88 reads (7%) | catalogued as COSV57363851; called by muse, mutect2
- IGHG3 | c.780C>T p.A260= | Silent (SNP) | VAF 15/237 reads (6%) | called by muse, mutect2
- KCNMB2 | c.501G>A p.R167= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV64201251; called by muse, mutect2
- LCT | c.2679C>T p.F893= | Silent (SNP) | VAF 6/138 reads (4%) | catalogued as rs1178928664, COSV51544858, COSV99928479; called by muse, mutect2
- LILRA4 | c.1167C>T p.H389= | Silent (SNP) | VAF 10/245 reads (4%) | catalogued as rs771948059, COSV52492975; called by muse, mutect2
- MAOB | c.1038C>A p.A346= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV65205839; called by muse, mutect2
- MARK1 | c.534T>C p.I178= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV65068555; called by muse, mutect2, varscan2
- MOCS3 | c.444C>T p.L148= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as rs1227494486, COSV54865931, COSV54866765; called by muse, mutect2
- MUC16 | c.27723C>T p.V9241= | Silent (SNP) | VAF 8/92 reads (9%) | catalogued as rs1330516077, COSV67464703, COSV67475647; called by muse, mutect2
- NID2 | c.111C>T p.F37= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV53498118; called by muse, mutect2, varscan2
- NKAP | c.30G>A p.P10= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs1396830357, COSV65056435; called by muse, mutect2, varscan2
- OR10G8 | c.735C>T p.I245= | Silent (SNP) | VAF 7/80 reads (9%) | catalogued as rs748588345, COSV70908219; called by muse, mutect2, varscan2
- PAPPA2 | c.36G>A p.A12= | Silent (SNP) | VAF 8/177 reads (5%) | catalogued as COSV62780248; called by muse, mutect2
- PCDH15 | c.4953G>A p.L1651= (on ENST00000644397 / NM_001354429.2; = p.L1593= on NM_001142771.2) | Silent (SNP) | VAF 16/250 reads (6%) | catalogued as COSV64704947; called by muse, mutect2
- PCDHA1 | c.1443C>T p.D481= | Silent (SNP) | VAF 8/138 reads (6%) | catalogued as rs562316404, COSV100974280, COSV65374130; called by muse, mutect2
- PRR16 | c.618G>A p.R206= (on ENST00000407149 / NM_001300783.2; = p.R183= on NM_016644.2) | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV65401146; called by muse, mutect2
- PTPRN2 | c.2436G>A p.R812= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV67041907, COSV67045042; called by muse, mutect2, varscan2
- RB1CC1 | c.1941C>T p.S647= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV50253972; called by muse, mutect2, varscan2
- RLF | c.2415C>T p.F805= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV65652169; called by muse, mutect2, varscan2
- RPS6KA6 | c.384G>A p.V128= | Silent (SNP) | VAF 6/85 reads (7%) | catalogued as rs1348951320, COSV53121886; called by muse, mutect2
- SCN1A | c.2766G>A p.K922= (on ENST00000303395 / NM_001202435.3; = p.K911= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/125 reads (11%) | catalogued as COSV57674954; called by muse, mutect2, varscan2
- SCN5A | c.2118C>T p.I706= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV61128947; called by muse, mutect2
- SIPA1L2 | c.1167C>T p.S389= | Silent (SNP) | VAF 17/203 reads (8%) | catalogued as COSV53392954, COSV53402149; called by muse, mutect2
- SLC12A4 | c.1257C>A p.S419= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV57931342; called by muse, mutect2
- SLC2A7 | c.411C>T p.S137= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV68901819; called by mutect2, varscan2
- SLC50A1 | c.600C>T p.I200= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as COSV100310485; called by muse, mutect2, varscan2
- SLC8A1 | c.1473C>T p.F491= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as COSV60477426; called by muse, mutect2
- STAB2 | c.4860C>T p.F1620= | Silent (SNP) | VAF 12/328 reads (4%) | catalogued as rs944580385, COSV66335802; called by muse, mutect2
- TAFA3 | c.273C>T p.I91= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1242261273, COSV62625023; called by muse, mutect2, varscan2
- TTN | c.39267C>T p.S13089= (on ENST00000591111; = p.S5665= on NM_003319.4) | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs879079561, COSV100632275, COSV60150638; called by muse, mutect2
- UNC5D | c.1590C>T p.I530= | Silent (SNP) | VAF 8/113 reads (7%) | catalogued as COSV54800856, COSV54805853; called by muse, mutect2
- VIL1 | c.675G>A p.V225= | Silent (SNP) | VAF 8/98 reads (8%) | called by muse, mutect2
- XIRP2 | c.2070G>A p.E690= (on ENST00000628543; = p.E865= on NM_152381.6) | Silent (SNP) | VAF 10/120 reads (8%) | catalogued as COSV54710737, COSV99744739; called by muse, mutect2
- ZNF665 | c.549C>T p.N183= (on ENST00000600412; = p.N248= on NM_024733.5 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 9/90 reads (10%) | catalogued as COSV67215879; called by muse, mutect2, varscan2
- OBSCN | c.11659+5072G>A | Intron (SNP) | VAF 6/63 reads (10%) | catalogued as rs868559478, COSV99483421; called by muse, mutect2
- SNORD115-14 | n.9G>A | RNA (SNP) | VAF 20/336 reads (6%) | catalogued as rs941709085; called by muse, mutect2
